FM case AD6729 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Kidney.
https://portal.gdc.cancer.gov/cases/a3893b79-a8ad-4b32-9d55-92ccb9209305

Male, 61.7 years: Sarcomatoid carcinoma (ICD-O-3 8033/3) of the kidney; primary biopsied or resected from the kidney. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
